Gene-level copy-number profile of tumor specimen C3L-05571-03 from CPTAC case C3L-05571, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage IIIC1; Tumor grade: G3; Age at diagnosis: 58.1 years (21,214 days).
Specimen C3L-05571-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file c0b0544f-1de7-405c-8a16-c0a05e87974d.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-05571-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,227 have no estimate.
https://portal.gdc.cancer.gov/files/0a5c3f39-24df-415b-a301-839db2bafba8

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 10,001; copy number 2: 46,516; copy number 3: 1,366; copy number 4: 314; copy number 5: 99; copy number 6: 15; copy number 7: 13; copy number 8: 52; copy number 10: 8; copy number 34: 1; copy number 35: 11.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 199 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:180,269,653–180,890,279, 7 genes, copy number 5 (within-gene range 4–5): ACBD6, VDAC1P4, MIR3121, OVAAL, Y_RNA, XPR1, U6.
- chr3:168,858,659–169,038,416, 5 genes, copy number 5: RPL21P43, LINC02082, AC092954.1, AC092954.2, LINC01997.
- chr6:151,452,258–152,637,801, 11 genes, copy number 6 (within-gene range 3–6): ARMT1, CCDC170, RNU6-813P, ESR1, AL356311.1, AL078582.2, AL078582.1, SYNE1, SYNE1-AS1, AL049548.1, RNA5SP223.
- chr9:39,072,767–39,288,315, 5 genes, copy number 7: CNTNAP3, RBM17P1, AL353729.2, AL353729.1, RN7SL640P.
- chr17:30,576,464–31,538,211, 48 genes, copy number 5 (within-gene range 2–5): AC005562.1, SMURF2P1, AC005562.2, SH3GL1P2, LRRC37BP1, RN7SL316P, SUZ12P1, AC127024.7, AC127024.3, AC127024.2, AC127024.8, CRLF3, AC127024.4, AC127024.5, AC127024.6, AC127024.1, ATAD5, AC130324.2, RNU6-298P, AC130324.1, TEFM, AC130324.3, ADAP2, AC138207.1, RN7SL138P, AC138207.5, AC138207.9, RNF135, AC138207.4, DPRXP4, AC138207.7, AC138207.3, AC138207.8, AC138207.6, AC138207.2, MIR4733, NF1, AC079915.1, OMG, EVI2B, AC134669.1, EVI2A, AK4P1, RAB11FIP4, RN7SL79P, RN7SL45P, AC003101.3, MIR4724.
- chr17:32,265,832–32,483,319, 16 genes, copy number 5: RHBDL3, AC026620.1, AC005899.4, C17orf75, AC005899.3, OOSP1P2, MIR632, ZNF207, AC005899.6, AC005899.7, AC005899.5, AC005899.8, AC005899.1, AC005899.2, PSMD11, Y_RNA.
- chr17:38,297,023–40,093,867, 84 genes, copy number 6–35 (within-gene range 1–35) (broad region; genes not listed).
- chr17:75,874,164–76,240,493, 23 genes, copy number 5 (within-gene range 3–5): TRIM47, AC087289.5, TRIM65, AC087289.2, MRPL38, AC087289.3, FBF1, ACOX1, AC087289.4, TEN1-CDK3, TEN1, CDK3, EVPL, SRP68, ZACN, GALR2, EXOC7, AC018665.1, MIR6868, FOXJ1, RNF157-AS1, RNF157, ATP5MGP6.

Autosomal genes at a single copy (total copy number 1): 8,555. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
